Surgical pathology report (de-identified scan), TCGA case TCGA-ED-A7PX, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Asterand, specimen TCGA-ED-A7PX-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor is located in a lobe, ill-margins with 5x4x4cm in size, soft, solid, yellow-white in cutting section.

Microscopic Description: Tumor cells form the trabecular patterns, or acinar or sheets patterns, infiltrating capsule or vessels or nerves. The tumor cells retain apolygonal shape and have round vesicular nuclei with prominent nucleoli. The amount of cytoplasm are moderate and the cytoplasm is basophilic or vacuolated. Nuclei are very irregularly large and hyperchromatic with prominent nucleoli. Mitoses are present. Tumor is necrotic. Stroma is marked fibrous and change.

Diagnosis Details: Hepatocellular carcinoma, poorly-differentiated

Comments:

Formatted Path Reports: LIVER TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor size: 5 x 4 x 4 cm

Focality: Single -

Histologic type: Hepatocellular carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Single tumor with vascular invasion

Lymph nodes: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-0-3

Carcinoma, hepatocellular ABS
8170/3

Site Liver
C22.0

9/12/13

Source: NCI Genomic Data Commons file 89ea8701-4c15-457b-8a0a-1b831167dd2e (TCGA-ED-A7PX.AF42396C-2DC9-4885-B7B1-D59BA1D2949A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).